Somatic mutation profile of tumor specimen C3N-02372-01 (aliquot CPT0137140011) from CPTAC case C3N-02372, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 54.3 years (19,828 days).
Specimen C3N-02372-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93e38d1f-5a9d-4baa-b8a5-6c8541b2d55f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02372-71 (Blood Derived Normal), aliquot CPT0137260002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc4db574-0224-44be-925e-78dd74e5c6ef

The open-access MAF lists 1,907 somatic variants for this specimen: 1,266 protein-altering or splice-affecting, 413 silent, 228 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 915, Silent 413, Frame Shift Del 216, Intron 115, Nonsense Mutation 51, 3'UTR 45, Frame Shift Ins 33, RNA 30, Splice Region 26, 5'Flank 17, 5'UTR 17, In Frame Del 13.

Variants (750 of 1,907; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCHE | c.1027dup p.T343Nfs*8 | Frame Shift Ins (INS) | VAF 13/112 reads (12%) | catalogued as rs754214624; ClinVar: likely pathogenic; called by mutect2, varscan2
- CHEK2 | c.735del p.F245Lfs*3 (on ENST00000382580 / NM_001005735.2; = p.F202Lfs*3 on NM_007194.4) | Frame Shift Del (DEL) | VAF 17/107 reads (16%) | catalogued as rs886039609; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- COL4A4 | c.4760del p.P1587Hfs*16 | Frame Shift Del (DEL) | VAF 19/141 reads (13%) | catalogued as rs1206142672, CM1310323; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 69/361 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 17/145 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FOLR1 | c.287G>A p.C96Y | Missense Mutation (SNP) | VAF 13/303 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057518816; ClinVar: likely pathogenic; called by muse, mutect2
- HNF1A | c.526+1G>A p.X176_splice | Splice Site (SNP) | VAF 99/527 reads (19%) | catalogued as rs1364708195, CS016021, CS083233, COSV57459449; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 54/288 reads (19%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NFE2L2 | c.246A>T p.E82D | Missense Mutation (SNP) | VAF 86/414 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67960116, COSV67960221; called by muse, mutect2, varscan2
- NOTCH3 | c.3016C>T p.R1006C | Missense Mutation (SNP) | VAF 39/248 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as rs1555727942, CM971069, COSV54639336; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NR3C2 | c.2755C>T p.Q919* | Nonsense Mutation (SNP) | VAF 44/270 reads (16%) | catalogued as rs1553986377, COSV60998679; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.437del p.L146* | Frame Shift Del (DEL) | VAF 50/305 reads (16%) | hotspot (GDC flag); catalogued as rs1114167627, COSV64292458; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC29A3 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387907066, CM100368, COSV64385004; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.2607del p.T871Lfs*13 | Frame Shift Del (DEL) | VAF 40/431 reads (9%) | catalogued as rs771808127, COSV55113098; called by mutect2, pindel
- AASDH | c.2974dup p.I992Nfs*7 | Frame Shift Ins (INS) | VAF 43/316 reads (14%) | catalogued as rs1373450456; called by mutect2, pindel, varscan2
- ABCA1 | c.5140G>A p.A1714T | Missense Mutation (SNP) | VAF 73/419 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.549); catalogued as rs758640488; called by muse, mutect2, varscan2
- ACIN1 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV52977395; called by muse, mutect2, varscan2
- ACLY | c.2363G>A p.R788Q | Missense Mutation (SNP) | VAF 76/419 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs782119490, COSV61253173; called by muse, mutect2, varscan2
- ACOX3 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs757530896; called by muse, mutect2, varscan2
- ACR | c.790del p.V264* | Frame Shift Del (DEL) | VAF 30/261 reads (11%) | catalogued as rs762191835; called by mutect2, pindel, varscan2
- ACSM2A | c.353A>G p.E118G (on ENST00000219054; = p.E39G on NM_001308169.2) | Missense Mutation (SNP) | VAF 56/291 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54590392; called by muse, mutect2, varscan2
- ACSM5 | c.323del p.G108Vfs*11 | Frame Shift Del (DEL) | VAF 32/262 reads (12%) | catalogued as rs746947661, COSV59374153; called by mutect2, pindel, varscan2
- ACTN4 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 79/584 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs1178103660; called by muse, mutect2, varscan2
- ACTR1B | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 91/514 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs775845413, COSV56703657; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 18/155 reads (12%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACY1 | c.658-4A>G | Splice Region (SNP) | VAF 99/589 reads (17%) | catalogued as rs1004697756; called by muse, mutect2, varscan2
- ADAM8 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs371368002; called by muse, mutect2, varscan2
- ADAMTS4 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.748); catalogued as rs115215539; called by muse, mutect2, varscan2
- ADAMTS5 | c.2537G>A p.R846H | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs762673375, COSV53186165; called by muse, mutect2, varscan2
- ADAMTS5 | c.2164G>A p.G722R | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs757271994, COSV53178718; called by muse, varscan2
- ADAMTS5 | c.2103del p.K702Sfs*3 | Frame Shift Del (DEL) | VAF 16/144 reads (11%) | catalogued as rs1460158960, COSV53182312; called by pindel, varscan2
- ADCY4 | c.1582del p.R528Gfs*3 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | catalogued as rs746788867; called by mutect2, pindel, varscan2
- ADCY7 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs545059286, COSV54271135; called by muse, mutect2, varscan2
- ADGRA1 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs369673758; called by mutect2, varscan2
- ADGRA1 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 86/381 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375880358; called by muse, mutect2, varscan2
- ADGRD2 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as rs1208960765; called by muse, mutect2, varscan2
- ADGRL1 | c.2782G>A p.G928S (on ENST00000340736 / NM_001008701.3; = p.G923S on NM_014921.5) | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as rs765501479; called by muse, mutect2
- ADHFE1 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.93); catalogued as rs746083019; called by muse, mutect2, varscan2
- ADM5 | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as rs865921197; called by muse, mutect2, varscan2
- AGAP5 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 133/734 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.796); catalogued as rs773341191; called by muse, mutect2, varscan2
- AHDC1 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); catalogued as rs779267543; ClinVar: likely benign; called by muse, varscan2
- AJM1 | c.968T>C p.M323T | Missense Mutation (SNP) | VAF 101/582 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1564377914; called by muse, mutect2, varscan2
- AKT3 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 9/74 reads (12%) | catalogued as rs1399248274, COSV55606625; called by muse, mutect2, varscan2
- AL645922.1 | c.1024del p.A342Pfs*9 | Frame Shift Del (DEL) | VAF 97/668 reads (15%) | catalogued as rs752447090, COSV54961301; called by mutect2, pindel, varscan2
- ALG13 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 46/259 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs374660036, COSV99323261; called by muse, mutect2, varscan2
- AMOTL1 | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.051); catalogued as rs764323867; called by muse, mutect2, varscan2
- AMPH | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs751656285, COSV57743907; called by muse, mutect2, varscan2
- ANAPC2 | c.2130del p.G711Afs*52 | Frame Shift Del (DEL) | VAF 54/384 reads (14%) | catalogued as COSV60568599; called by mutect2, pindel, varscan2
- ANK2 | c.11824C>T p.R3942C | Missense Mutation (SNP) | VAF 72/469 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1344245343; called by muse, mutect2, varscan2
- ANKFY1 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 79/519 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.055); catalogued as rs1239323463; called by muse, mutect2, varscan2
- ANKRD11 | c.4798C>T p.R1600W | Missense Mutation (SNP) | VAF 48/328 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1300503919, COSV56367009; called by muse, mutect2, varscan2
- ANKRD36 | c.2099C>T p.S700L | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.393); catalogued as rs1056513329; called by muse, mutect2, varscan2
- ANO6 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 62/340 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs754292177; called by muse, mutect2, varscan2
- ANXA11 | c.1458G>A p.S486= | Splice Region (SNP) | VAF 12/53 reads (23%) | catalogued as rs1209281718; called by muse, mutect2, varscan2
- AOC1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.017); catalogued as rs769572318; called by muse, mutect2, varscan2
- AP1G2 | c.1345del p.A449Pfs*84 | Frame Shift Del (DEL) | VAF 51/478 reads (11%) | catalogued as rs749982998; called by mutect2, pindel, varscan2
- AP2A2 | c.2006del p.P669Lfs*67 | Frame Shift Del (DEL) | VAF 66/357 reads (18%) | catalogued as rs770443312, COSV59961800; called by mutect2, varscan2
- APBB1IP | c.843del p.E282Kfs*9 | Frame Shift Del (DEL) | VAF 8/65 reads (12%) | catalogued as rs1478302580; called by mutect2, pindel, varscan2
- APC | c.4196G>A p.R1399H | Missense Mutation (SNP) | VAF 36/253 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1431515214, COSV57339858, COSV57361062; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 23/132 reads (17%) | catalogued as rs749401724; called by mutect2, varscan2
- AQP4 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 106/509 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.359); catalogued as rs760876531, COSV67219280; called by muse, mutect2, varscan2
- AQP8 | c.363del p.M122Cfs*10 | Frame Shift Del (DEL) | VAF 25/212 reads (12%) | catalogued as rs759782104; called by mutect2, pindel, varscan2
- ARFGAP2 | c.1433T>C p.V478A | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1255616160; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 32/213 reads (15%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARHGAP32 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 27/151 reads (18%) | catalogued as COSV59851476; called by muse, mutect2, varscan2
- ARHGAP44 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 10/140 reads (7%) | catalogued as COSV52397154; called by muse, mutect2
- ARHGAP6 | c.2416G>A p.A806T (on ENST00000337414 / NM_013427.3; = p.A603T on NM_013423.3) | Missense Mutation (SNP) | VAF 53/279 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.011); catalogued as COSV57300975; called by muse, mutect2, varscan2
- ARHGDIG | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs201741302; called by muse, mutect2, varscan2
- ARHGEF38 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1202582797, COSV104435315; called by muse, mutect2, varscan2
- ARID5B | c.1489del p.I497* | Frame Shift Del (DEL) | VAF 16/106 reads (15%) | catalogued as rs201178069; called by mutect2, pindel, varscan2
- ARMC5 | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 12/404 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs1225702640; called by muse, mutect2
- ARMH1 | c.920+6C>T | Splice Region (SNP) | VAF 36/194 reads (19%) | catalogued as rs1469911244, COSV62637313; called by muse, mutect2, varscan2
- ARNT | c.1783del p.R595Gfs*11 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | catalogued as COSV62230627; called by mutect2, pindel
- ART3 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.061); catalogued as rs138370369; called by muse, varscan2
- ASH1L | c.8396G>A p.R2799Q (on ENST00000368346 / NM_001366177.2; = p.R2794Q on NM_018489.3) | Missense Mutation (SNP) | VAF 42/236 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs757446840; called by muse, mutect2, varscan2
- ASPDH | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 30/182 reads (16%) | catalogued as rs1247855449; called by muse, mutect2, varscan2
- ATF6B | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 43/368 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.644); catalogued as rs1273067618; called by muse, mutect2, varscan2
- ATG9B | c.293del p.P98Qfs*8 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as rs770350293; called by mutect2, pindel
- ATM | c.2495G>A p.R832H | Missense Mutation (SNP) | VAF 32/268 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs199875915, COSV53762915, COSV53776325; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP11B | c.2380C>T p.R794C | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs995122602, COSV60028906; called by muse, mutect2
- ATP13A2 | c.1542+8C>T | Splice Region (SNP) | VAF 40/271 reads (15%) | catalogued as rs780521605; called by muse, mutect2, varscan2
- ATP2C2 | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs373784599; called by muse, mutect2, varscan2
- ATP4A | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs549194754; called by muse, mutect2
- ATP8B1 | c.1805G>A p.R602Q | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758353144, CM117172, COSV52180194; called by muse, mutect2, varscan2
- ATP9A | c.1213C>T p.R405W | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs751071851; called by muse, mutect2, varscan2
- AVPR1A | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 51/307 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV54546979; called by muse, mutect2, varscan2
- AXL | c.195del p.E66Rfs*32 | Frame Shift Del (DEL) | VAF 92/556 reads (17%) | catalogued as COSV56565852; called by mutect2, pindel, varscan2
- B3GNT8 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.074); catalogued as rs373910300; called by muse, mutect2, varscan2
- B3GNT9 | c.717_719del p.L240del | In Frame Del (DEL) | VAF 45/187 reads (24%) | catalogued as rs775649567; called by mutect2, pindel, varscan2
- BAHCC1 | c.6293C>T p.A2098V | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.543); catalogued as COSV100311609; called by muse, mutect2, varscan2
- BAIAP3 | c.2155G>A p.V719M | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs372682330; called by muse, mutect2, varscan2
- BAZ1B | c.3722G>A p.R1241H | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782273444, COSV59994954; called by muse, mutect2, varscan2
- BAZ2A | c.2012G>A p.R671Q | Missense Mutation (SNP) | VAF 103/552 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as rs982765140; called by muse, mutect2, varscan2
- BCL11B | c.2390C>T p.T797M (on ENST00000357195 / NM_001282237.2; = p.T726M on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/387 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61733099; called by muse, mutect2, varscan2
- BDH1 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746191768; called by muse, mutect2, varscan2
- BEND3 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs1316134137, COSV64681621; called by muse, mutect2, varscan2
- BICDL2 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 41/267 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs369693971; called by muse, mutect2, varscan2
- BIN1 | c.1412C>T p.A471V (on ENST00000316724 / NM_001320642.1; = p.A332V on NM_004305.4) | Missense Mutation (SNP) | VAF 67/429 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs746346952; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2323G>A p.V775M | Missense Mutation (SNP) | VAF 63/366 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs756778477; called by muse, mutect2, varscan2
- BMP1 | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs760413911; called by muse, mutect2, varscan2
- BMP2K | c.3244C>T p.H1082Y | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99785132; called by muse, mutect2, varscan2
- BMPR1A | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 80/529 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.894); catalogued as rs779371501; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BNIPL | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 56/315 reads (18%) | catalogued as rs774049101, COSV54849675; called by muse, mutect2, varscan2
- BOC | c.3296C>T p.P1099L | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.017); catalogued as rs746269289, COSV56347461; called by muse, mutect2, varscan2
- BOD1L2 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs913406942, COSV73996893; called by muse, mutect2, varscan2
- BRD4 | c.2446G>A p.V816I | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.018); catalogued as rs760576705, COSV54596037; called by muse, mutect2
- BRSK1 | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs746043904, COSV58665984; called by mutect2, varscan2
- BRSK1 | c.1568C>T p.T523M | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1215335381, COSV100474716; called by muse, mutect2, varscan2
- BZW1 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.113); catalogued as COSV63350333; called by mutect2, varscan2
- C19orf38 | c.232A>G p.S78G | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1160078331; called by muse, mutect2
- C1orf159 | c.1127G>A p.R376H (on ENST00000379339 / NM_001330306.2; = p.R194H on NM_017891.5) | Missense Mutation (SNP) | VAF 84/453 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); catalogued as rs780106133, COSV53883482; called by muse, mutect2, varscan2
- C4orf54 | c.4865A>G p.Y1622C | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs977166490; called by muse, mutect2, varscan2
- CACNA1A | c.7529A>G p.D2510G | Missense Mutation (SNP) | VAF 63/317 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756719396; called by muse, mutect2, varscan2
- CACNA1H | c.6031C>T p.R2011W | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs753241781, COSV99326742; ClinVar: uncertain significance; called by muse, mutect2
- CACNG2 | c.644C>T p.T215M | Missense Mutation (SNP) | VAF 124/604 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV100268991; called by muse, mutect2, varscan2
- CANT1 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs569632479; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARD6 | c.2331G>T p.Q777H | Missense Mutation (SNP) | VAF 54/241 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54565710; called by muse, mutect2, varscan2
- CASP12 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as rs754098342; called by muse, mutect2, varscan2
- CC2D1B | c.220dup p.L74Pfs*47 | Frame Shift Ins (INS) | VAF 19/203 reads (9%) | catalogued as rs761754886; called by pindel, varscan2
- CCDC120 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as COSV100900696; called by muse, mutect2, varscan2
- CCDC154 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 59/280 reads (21%) | catalogued as rs567595349; called by muse, mutect2, varscan2
- CCDC158 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 58/308 reads (19%) | catalogued as rs1165176101, COSV101187339; called by muse, mutect2, varscan2
- CCDC168 | c.21051del p.F7017Lfs*25 | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | catalogued as rs397851855; called by mutect2, varscan2
- CCDC34 | c.806del p.K269Rfs*3 | Frame Shift Del (DEL) | VAF 23/159 reads (14%) | catalogued as COSV60820918, COSV60821042; called by mutect2, pindel, varscan2
- CCDC78 | c.1277C>T p.T426M | Missense Mutation (SNP) | VAF 61/280 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0.013); catalogued as rs142180051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCIN | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 38/299 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs765562220, COSV58725046; called by muse, mutect2, varscan2
- CCM2L | c.1656C>G p.D552E | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as rs1170023018, COSV52950570; called by muse, mutect2
- CCP110 | c.2434C>T p.R812C | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66816515, COSV66817745; called by muse, mutect2, varscan2
- CCZ1 | c.1370dup p.N457Kfs*6 | Frame Shift Ins (INS) | VAF 10/52 reads (19%) | catalogued as rs1484671183; called by mutect2, varscan2
- CDC45 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs141618921; called by muse, mutect2, varscan2
- CDHR2 | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 82/529 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.25); catalogued as rs1214276632; called by muse, mutect2, varscan2
- CDR2L | c.1156G>A p.V386M | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1156489638, COSV100464549; called by muse, mutect2, varscan2
- CELSR3 | c.4085C>T p.A1362V | Missense Mutation (SNP) | VAF 55/311 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.174); catalogued as COSV51185204; called by muse, mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs1325731082; called by mutect2, pindel, varscan2
- CEP164 | c.3910C>T p.R1304W | Missense Mutation (SNP) | VAF 60/340 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs139444171; called by muse, mutect2, varscan2
- CEP170B | c.3242G>A p.R1081Q (on ENST00000453495; = p.R1010Q on NM_015005.3) | Missense Mutation (SNP) | VAF 41/287 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as rs372887006; called by muse, mutect2, varscan2
- CFAP57 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 54/304 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs756815800, COSV65264756; called by muse, mutect2, varscan2
- CFAP65 | c.1775del p.P592Lfs*8 | Frame Shift Del (DEL) | VAF 57/268 reads (21%) | catalogued as rs778664468; called by mutect2, pindel, varscan2
- CFAP97 | c.481del p.S161Afs*2 | Frame Shift Del (DEL) | VAF 32/190 reads (17%) | catalogued as rs34798240; called by mutect2, pindel, varscan2
- CHKB | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 103/552 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs748462496, COSV56416175; called by muse, mutect2, varscan2
- CHST8 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 44/291 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as rs368651953, COSV99381069; called by muse, mutect2, varscan2
- CLASP1 | c.3400G>A p.G1134R | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.921); catalogued as rs775092504, COSV55329747; called by muse, mutect2, varscan2
- CLASRP | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0); catalogued as rs747032294; called by muse, mutect2, varscan2
- CLCN4 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as rs201381518; ClinVar: uncertain significance; called by muse, mutect2
- CLEC7A | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.84); catalogued as rs373489756; called by muse, mutect2, varscan2
- CLSPN | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 57/351 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751657804; called by muse, mutect2, varscan2
- CNOT3 | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs138688054; called by muse, mutect2, varscan2
- CNTN3 | c.2237C>T p.T746I | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV55185594; called by muse, mutect2, varscan2
- CNTN4 | c.135del p.V46* | Frame Shift Del (DEL) | VAF 23/247 reads (9%) | catalogued as COSV68568603; called by mutect2, pindel
- CNTN4 | c.1534G>T p.G512* | Nonsense Mutation (SNP) | VAF 32/330 reads (10%) | catalogued as COSV61876363; called by muse, mutect2, varscan2
- CNTNAP5 | c.2073G>A p.P691= | Splice Region (SNP) | VAF 20/72 reads (28%) | catalogued as rs767269123; called by muse, mutect2
- COG1 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 86/474 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs770355508, COSV55428394; called by muse, mutect2, varscan2
- COL16A1 | c.2538G>A p.P846= | Splice Region (SNP) | VAF 21/151 reads (14%) | catalogued as rs755760253, COSV54704087, COSV54705041; called by muse, mutect2, varscan2
- COL1A1 | c.3778C>T p.R1260C | Missense Mutation (SNP) | VAF 39/347 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1555571800, COSV56806665; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL1A1 | c.910del p.R304Vfs*237 | Frame Shift Del (DEL) | VAF 62/461 reads (13%) | catalogued as COSV56803507; called by mutect2, pindel, varscan2
- COL7A1 | c.2666C>T p.P889L | Missense Mutation (SNP) | VAF 126/524 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.097); catalogued as rs146783561; called by muse, mutect2, varscan2
- CREBBP | c.3305A>G p.Y1102C | Missense Mutation (SNP) | VAF 66/560 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52134606; called by muse, mutect2, varscan2
- CRMP1 | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 50/359 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.011); catalogued as rs533613606; called by muse, mutect2, varscan2
- CST1 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 40/220 reads (18%) | catalogued as rs756924682; called by mutect2, pindel, varscan2
- CTC1 | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs773945643; called by muse, mutect2
- CTNND2 | c.3613C>T p.R1205C | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs377404994, COSV100481721; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1131dup p.S378Ifs*20 | Frame Shift Ins (INS) | VAF 30/173 reads (17%) | catalogued as rs763972753; called by mutect2, pindel, varscan2
- CUX1 | c.1252C>T p.R418C (on ENST00000437600 / NM_181500.4; = p.R420C on NM_001913.5) | Missense Mutation (SNP) | VAF 45/280 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as rs782171972; called by muse, mutect2, varscan2
- CUX1 | c.1525C>T p.R509C (on ENST00000437600 / NM_181500.4; = p.R511C on NM_001913.5) | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs782713359; called by muse, mutect2, varscan2
- CYP2A13 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 49/264 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); catalogued as rs1469345892, COSV57839905; called by muse, mutect2, varscan2
- CYSLTR1 | c.351G>T p.M117I | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV64820939; called by muse, mutect2, varscan2
- DAG1 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.213); catalogued as rs755343255; called by muse, mutect2, varscan2
- DAPK1 | c.3775C>T p.R1259W | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs771500801, COSV63783862; called by muse, mutect2, varscan2
- DCAF4L2 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 55/301 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs749646973, COSV60477172; called by muse, mutect2, varscan2
- DDR1 | c.875C>T p.T292M | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs376283924; called by muse, mutect2, varscan2
- DDX3X | c.1805G>A p.R602Q (on ENST00000399959; = p.R603Q on NM_001356.5) | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101302338; called by muse, mutect2, varscan2
- DDX43 | c.1092del p.G365Vfs*2 | Frame Shift Del (DEL) | VAF 18/134 reads (13%) | catalogued as rs1424884917, COSV64836411; called by mutect2, pindel, varscan2
- DDX55 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 56/278 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766244307; called by muse, mutect2, varscan2
- DDX60L | c.3503del p.N1168Tfs*25 | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | catalogued as rs772416332; called by mutect2, varscan2
- DENND2B | c.3040G>A p.D1014N | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as rs1367610451; called by muse, mutect2, varscan2
- DEPDC1 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs371164383; called by muse, mutect2, varscan2
- DGKA | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 20/174 reads (11%) | catalogued as COSV59388757; called by muse, mutect2, varscan2
- DMRT2 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 58/313 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.043); catalogued as rs370378831; called by muse, mutect2, varscan2
- DMTF1 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV58688342; called by muse, mutect2, varscan2
- DMTN | c.274T>C p.S92P | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV56114313; called by muse, mutect2, varscan2
- DMXL2 | c.8876C>T p.T2959I | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs762386288; called by muse, mutect2, varscan2
- DNAH1 | c.4265C>T p.T1422M | Missense Mutation (SNP) | VAF 61/319 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.332); catalogued as rs745784100, COSV101325747; called by muse, mutect2, varscan2
- DNAH1 | c.9238C>T p.R3080C | Missense Mutation (SNP) | VAF 46/254 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs757152337; called by muse, mutect2, varscan2
- DNAH17 | c.2132G>A p.R711Q | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs755475646, COSV101103710; called by muse, mutect2, varscan2
- DNAH2 | c.2761C>T p.R921C | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as rs148215103; called by muse, mutect2, varscan2
- DNAJC1 | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 69/393 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as rs774109956; called by muse, mutect2, varscan2
- DNAJC13 | c.3796C>T p.R1266W | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs948054040, COSV53448137; called by muse, mutect2, varscan2
- DNAL4 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 52/283 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as rs199652920, COSV99326195; called by muse, mutect2, varscan2
- DNMT3A | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 41/269 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs1308281604; called by muse, mutect2, varscan2
- DOCK8 | c.2725G>A p.A909T | Missense Mutation (SNP) | VAF 74/392 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs750025996, COSV101209841; called by muse, mutect2, varscan2
- DPF3 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as rs553474073; called by muse, mutect2, varscan2
- DPP10 | c.2017G>A p.V673M | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs764715614, COSV59662512; called by muse, mutect2, varscan2
- DPY19L4 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs773956154, COSV68963200; called by muse, mutect2, varscan2
- DSEL | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV100026144; called by muse, mutect2, varscan2
- DSG2 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 60/306 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs369078344; called by muse, mutect2, varscan2
- DST | c.3044G>A p.R1015H (on ENST00000361203 / NM_001374722.1; = p.R689H on NM_001723.6) | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1003908769, COSV55025131; called by muse, mutect2
- DUSP8 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.264); catalogued as rs745437361; called by muse, mutect2, varscan2
- DYNC1I2 | c.105del p.E36Kfs*34 | Frame Shift Del (DEL) | VAF 14/96 reads (15%) | catalogued as rs755197346; called by mutect2, varscan2
- E2F8 | c.532T>C p.Y178H | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51466477; called by muse, mutect2, varscan2
- EBF3 | c.910G>A p.E304K (on ENST00000355311 / NM_001375392.1; = p.E295K on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); catalogued as COSV62482718; called by muse, mutect2, varscan2
- EEPD1 | c.1663G>A p.G555R | Missense Mutation (SNP) | VAF 16/257 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs748408838, COSV54203588; called by muse, mutect2
- EFR3A | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs773514654, COSV54455094; called by muse, mutect2
- EGFR | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.163); catalogued as rs754646330; called by muse, mutect2, varscan2
- EGR4 | c.1655G>A p.R552H (on ENST00000545030; = p.R449H on NM_001965.4) | Missense Mutation (SNP) | VAF 69/406 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1314701114; called by muse, mutect2, varscan2
- EIF2AK1 | c.277+1G>A p.X93_splice | Splice Site (SNP) | VAF 16/164 reads (10%) | catalogued as rs148495208; called by muse, mutect2
- EIF3D | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.148); catalogued as rs138603428; called by muse, mutect2, varscan2
- EIF4B | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as COSV50404827; called by muse, mutect2
- ELF5 | c.346G>A p.E116K (on ENST00000312319 / NM_198381.2; = p.E106K on NM_001422.4) | Missense Mutation (SNP) | VAF 62/382 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.898); catalogued as rs367861770; called by muse, mutect2, varscan2
- ELFN1 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.115); catalogued as rs1373515462; called by muse, mutect2, varscan2
- EMC4 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); catalogued as rs1439057985; called by muse, varscan2
- EMILIN1 | c.2407C>T p.R803C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs1422658061; called by muse, mutect2
- EML5 | c.5368C>T p.R1790W (on ENST00000380664; = p.R1798W on NM_183387.3) | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV61351770; called by muse, mutect2, varscan2
- EMP3 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 46/307 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs775165167, COSV53156850; called by muse, mutect2, varscan2
- EPHA5 | c.698del p.C233Sfs*35 | Frame Shift Del (DEL) | VAF 38/206 reads (18%) | catalogued as COSV56662100; called by mutect2, pindel, varscan2
- EPHA7 | c.1874C>T p.A625V | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99054397; called by muse, mutect2, varscan2
- EPN1 | c.833del p.G278Afs*164 (on ENST00000270460 / NM_001321263.1; = p.G253Afs*163 on NM_013333.3) | Frame Shift Del (DEL) | VAF 18/102 reads (18%) | catalogued as rs755604942; called by mutect2, pindel, varscan2
- EPN1 | c.1469G>A p.R490Q (on ENST00000270460 / NM_001321263.1; = p.R464Q on NM_013333.3) | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs765609502, COSV50045775; called by muse, mutect2, varscan2
- EPRS1 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 39/194 reads (20%) | catalogued as rs756747498; called by muse, varscan2
- ERICH4 | c.64del p.Q22Rfs*3 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | catalogued as rs567420399; called by mutect2, pindel, varscan2
- ETV7 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.36); catalogued as COSV60317488; called by muse, mutect2, varscan2
- EXOSC6 | c.341del p.P114Rfs*106 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | catalogued as rs1313952659; called by mutect2, pindel, varscan2
- EZH2 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 53/232 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as CM1312126, COSV57462682; called by muse, mutect2, varscan2
- F5 | c.6584del p.P2195Qfs*49 | Frame Shift Del (DEL) | VAF 24/191 reads (13%) | catalogued as CM095206; called by mutect2, pindel, varscan2
- F8 | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 13/243 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.609); catalogued as rs1557280436; called by muse, mutect2
- FADS6 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 63/315 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.244); catalogued as rs531632048, COSV100043902, COSV59602113; called by muse, mutect2, varscan2
- FAM120C | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs933418764, COSV100070364; called by muse, mutect2, varscan2
- FAM171A2 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.566); catalogued as rs80216620; called by muse, mutect2, varscan2
- FAM180A | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs767403406, COSV58528018; called by muse, varscan2
- FAM207A | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 63/491 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs148502379; called by muse, mutect2, varscan2
- FAM221B | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 86/374 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs1010181315, COSV52414800; called by muse, mutect2, varscan2
- FAM228A | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); catalogued as rs372838900; called by muse, mutect2, varscan2
- FAM47C | c.1931C>T p.P644L | Missense Mutation (SNP) | VAF 102/638 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as rs781807491; called by muse, varscan2
- FAM98C | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768768718; called by muse, mutect2, varscan2
- FANCM | c.3347A>G p.H1116R | Missense Mutation (SNP) | VAF 57/296 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs778621580; called by muse, mutect2, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs746983128; called by mutect2, varscan2
- FARS2 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.858); catalogued as rs746837108, COSV51175680; called by muse, mutect2, varscan2
- FASTKD5 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 57/247 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs147076248; called by muse, mutect2, varscan2
- FBXL3 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs369788246; called by muse, mutect2, varscan2
- FBXL5 | c.1314G>A p.M438I | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs758165511; called by muse, mutect2, varscan2
- FBXL7 | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 46/268 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as rs762341690, COSV61641347; called by muse, mutect2, varscan2
- FCGBP | c.8774G>A p.R2925Q | Missense Mutation (SNP) | VAF 48/630 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.217); catalogued as rs781059374; called by muse, mutect2, varscan2
- FCHO1 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs144793428; called by muse, mutect2, varscan2
- FGFR4 | c.2266G>A p.D756N | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs192201146; called by muse, mutect2, varscan2
- FLNC | c.2363C>T p.T788M | Missense Mutation (SNP) | VAF 66/375 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1010774264; called by muse, mutect2, varscan2
- FLRT3 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1390361437, COSV53973493; called by muse, mutect2, varscan2
- FMNL2 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs377550607; called by muse, varscan2
- FMR1 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54426577, COSV54428337; called by muse, mutect2, varscan2
- FNBP4 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 52/339 reads (15%) | catalogued as COSV55447247; called by muse, mutect2, varscan2
- FNIP2 | c.1743del p.I582Sfs*94 | Frame Shift Del (DEL) | VAF 34/277 reads (12%) | catalogued as COSV52437011; called by mutect2, pindel, varscan2
- FOXE3 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 95/534 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58632382; called by muse, mutect2, varscan2
- FOXJ1 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.085); catalogued as rs776758063; called by muse, mutect2, varscan2
- FREM2 | c.9244C>T p.R3082C | Missense Mutation (SNP) | VAF 55/330 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs375203975; called by muse, mutect2, varscan2
- FUS | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs201772423, CM155569; called by muse, mutect2, varscan2
- FXYD2 | c.65-5C>T | Splice Region (SNP) | VAF 48/195 reads (25%) | catalogued as rs1407414708; called by muse, varscan2
- FYCO1 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 76/415 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs760218585, COSV56115231; called by muse, mutect2, varscan2
- FZD9 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781972322; called by muse, mutect2, varscan2
- GABRB3 | c.1195G>T p.G399* | Nonsense Mutation (SNP) | VAF 36/188 reads (19%) | catalogued as COSV100162285, COSV54685523; called by muse, mutect2, varscan2
- GABRG1 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.929); catalogued as rs769209641, COSV54955110; called by muse, mutect2, varscan2
- GALNT1 | c.690_692del p.X230_splice | Splice Site (DEL) | VAF 10/101 reads (10%) | catalogued as rs769589721; called by mutect2, pindel
- GALR1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 68/348 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV55318099; called by muse, varscan2
- GCC2 | c.3653del p.N1218Tfs*9 | Frame Shift Del (DEL) | VAF 8/69 reads (12%) | catalogued as rs760884932; called by mutect2, pindel, varscan2
- GEMIN8 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs749314407, COSV60550720; called by muse, mutect2, varscan2
- GHDC | c.1138G>A p.V380I | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs370923206; called by muse, mutect2, varscan2
- GK3P | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 68/474 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as rs1553960280; called by muse, mutect2, varscan2
- GLB1L3 | c.1233del p.V412* | Frame Shift Del (DEL) | VAF 23/176 reads (13%) | catalogued as rs758614894; called by mutect2, pindel, varscan2
- GLIS3 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs559065074, COSV100174335; called by muse, mutect2, varscan2
- GLIS3 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 40/309 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as rs529724687, COSV60932870; called by muse, mutect2, varscan2
- GNAS | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 68/343 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs1240097574, COSV100005455; called by muse, mutect2, varscan2
- GNAZ | c.612dup p.Q205Afs*35 | Frame Shift Ins (INS) | VAF 26/140 reads (19%) | catalogued as rs752075537; called by mutect2, varscan2
- GP1BA | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.02); catalogued as rs763902783; called by muse, varscan2
- GP1BA | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.441); catalogued as rs1483629593; called by muse, varscan2
- GPR183 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1434828575; called by muse, mutect2
- GPR37 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as rs1257956705, COSV58256365; called by muse, mutect2, varscan2
- GPR50 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs1433023729; called by muse, mutect2, varscan2
- GPR68 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.893); catalogued as rs1336275133, COSV53176039; called by muse, mutect2, varscan2
- GREB1 | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 91/483 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs904016073; called by muse, mutect2, varscan2
- GRIN2A | c.4205G>A p.R1402Q | Missense Mutation (SNP) | VAF 60/427 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs74935155, COSV100411016, COSV58053824; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRIN2B | c.3316G>A p.E1106K | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199799650, COSV74204786, COSV74206480; called by muse, mutect2, varscan2
- GRIN2D | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs778297666; called by muse, mutect2, varscan2
- GRM1 | c.2944G>A p.V982M | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV51166468; called by muse, mutect2
- GRM7 | c.1130C>T p.T377M | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1350216066, COSV63136870; called by muse, mutect2, varscan2
- GRM8 | c.2158del p.H720Tfs*12 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as COSV58842099; called by mutect2, pindel, varscan2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 16/61 reads (26%) | catalogued as rs754199513; called by mutect2, varscan2
- GTF2F1 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs150745438; called by muse, mutect2, varscan2
- GTF2IRD1 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 44/387 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.221); catalogued as rs782212975; called by muse, mutect2, varscan2
- GUCA1B | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 96/558 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs767394548, COSV57835066; called by muse, mutect2, varscan2
- H4C6 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as COSV66685376; called by muse, mutect2
- HAND2 | c.247del p.V83Cfs*16 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as CM105646; called by mutect2, varscan2
- HAS1 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 65/350 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1257203882, COSV55787682; called by muse, mutect2, varscan2
- HDAC10 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 57/348 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs1389114026; called by muse, mutect2, varscan2
- HDHD3 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs754070311; called by muse, mutect2, varscan2
- HEATR5A | c.4699G>A p.V1567M | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.092); catalogued as rs756297444; called by muse, mutect2, varscan2
- HECW2 | c.3419+3A>G | Splice Region (SNP) | VAF 34/183 reads (19%) | catalogued as rs202033151; called by muse, mutect2, varscan2
- HERC1 | c.14456C>T p.P4819L | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756534965, COSV71248143; called by muse, mutect2, varscan2
- HGD | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 51/463 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52195765; called by muse, mutect2, varscan2
- HGFAC | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.738); catalogued as rs772590999; called by muse, mutect2, varscan2
- HMCN1 | c.11378G>A p.R3793H | Missense Mutation (SNP) | VAF 50/299 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs768205453, COSV54932305; called by muse, mutect2, varscan2
- HOXD12 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 30/281 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101184221; called by muse, mutect2, varscan2
- HRH2 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 87/366 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1438986908, COSV99199698; called by muse, mutect2, varscan2
- HRNR | c.6215G>T p.G2072V | Missense Mutation (SNP) | VAF 87/788 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs750662561; called by muse, varscan2
- IFT140 | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 53/335 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs373111085, CM123481; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGDCC4 | c.1939G>A p.V647M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs373976279; called by muse, mutect2
- IGF2R | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 54/311 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs919932123, COSV63627392; called by muse, mutect2, varscan2
- IL16 | c.3521C>T p.T1174M (on ENST00000302987 / NM_172217.5; = p.T473M on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/487 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762883223; called by muse, mutect2, varscan2
- IL1R1 | c.864_866del p.R289del | In Frame Del (DEL) | VAF 7/51 reads (14%) | catalogued as rs763186299; called by pindel, varscan2
- IL1RL2 | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200652363; called by muse, mutect2, varscan2
- IL34 | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 38/252 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759251394; called by muse, mutect2, varscan2
- IL4R | c.1702G>A p.V568I | Missense Mutation (SNP) | VAF 46/296 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs749041212, COSV50160433; called by muse, mutect2, varscan2
- INCENP | c.1605C>T p.V535= | Splice Region (SNP) | VAF 34/211 reads (16%) | catalogued as rs527336992, COSV53916062; called by muse, mutect2, varscan2
- INPPL1 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773085707, COSV53357373; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 22/117 reads (19%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INSC | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 31/258 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs201061980, COSV101088665; called by muse, mutect2, varscan2
- INSRR | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs756613475, COSV63875766; called by muse, mutect2, varscan2
- INTS5 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.172); catalogued as rs1024650635, COSV57952450; called by muse, mutect2
- IP6K1 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 107/592 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.895); catalogued as rs770036929; called by muse, mutect2, varscan2
- IQSEC3 | c.1060C>T p.R354C (on ENST00000538872 / NM_001170738.2; = p.R51C on NM_015232.1) | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs532177168; called by muse, mutect2, varscan2
- IRX2 | c.1151A>G p.Y384C | Missense Mutation (SNP) | VAF 12/422 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs867335815, COSV100121580; called by muse, mutect2
- IRX3 | c.1113del p.S372Lfs*151 | Frame Shift Del (DEL) | VAF 15/95 reads (16%) | catalogued as rs759120276; called by mutect2, pindel, varscan2
- ITFG1 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs758393141, COSV57748092; called by muse, mutect2, varscan2
- ITGB2 | c.1102del p.E368Sfs*35 (on ENST00000302347; = p.E344Sfs*35 on NM_000211.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 70/546 reads (13%) | catalogued as rs1265749759, CM1513873; called by mutect2, pindel, varscan2
- ITPRIPL2 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 34/326 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV101198160; called by muse, mutect2, varscan2
- ITSN1 | c.4640G>A p.R1547H | Missense Mutation (SNP) | VAF 51/308 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs374602007; called by muse, mutect2, varscan2
- JADE2 | c.2315G>A p.R772Q | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs560524571; called by muse, mutect2
- JAK3 | c.3254G>A p.R1085Q | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV71685372; called by muse, mutect2, varscan2
- JUP | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782354654, COSV60278601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KANSL3 | c.2506G>A p.A836T (on ENST00000666923 / NM_001349262.2; = p.A810T on NM_001115016.3) | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1252975092; called by muse, mutect2, varscan2
- KANSL3 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs759529862, COSV62616040; called by muse, mutect2, varscan2
- KAT2B | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.03); catalogued as rs771195931, COSV55430172; called by muse, mutect2, varscan2
- KAT6B | c.2696G>A p.R899H | Missense Mutation (SNP) | VAF 56/314 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs761702778, COSV54755783; called by muse, mutect2, varscan2
- KATNIP | c.2653C>T p.R885W | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs368772505; called by muse, mutect2, varscan2
- KCNC1 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1247061581, COSV56392291; called by muse, mutect2
- KCNC1 | c.1370del p.K457Rfs*20 | Frame Shift Del (DEL) | VAF 120/330 reads (36%) | catalogued as COSV99789491; called by mutect2, varscan2
- KCNF1 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 48/234 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV54465215; called by muse, mutect2, varscan2
- KCNF1 | c.1094T>C p.I365T | Missense Mutation (SNP) | VAF 59/297 reads (20%) | SIFT tolerated (1); PolyPhen possibly damaging (0.637); catalogued as COSV54464192; called by muse, mutect2, varscan2
- KCNG1 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100856993; called by muse, mutect2, varscan2
- KCNH4 | c.642del p.S215Lfs*62 | Frame Shift Del (DEL) | VAF 45/291 reads (15%) | catalogued as COSV99236896; called by mutect2, pindel, varscan2
- KCNMA1 | c.3503C>T p.P1168L (on ENST00000286628 / NM_001161352.2; = p.P1110L on NM_002247.4) | Missense Mutation (SNP) | VAF 59/318 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs1219705887; called by muse, mutect2, varscan2
- KCNV1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749043466, COSV52088536, COSV99819118; called by muse, mutect2, varscan2
- KCNV2 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772682207, COSV66055580; called by muse, mutect2, varscan2
- KCTD13 | c.421del p.R141Gfs*13 | Frame Shift Del (DEL) | VAF 51/412 reads (12%) | catalogued as rs766440565; called by mutect2, varscan2
- KCTD9 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as rs780538380; called by muse, mutect2, varscan2
- KDM5C | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 50/422 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1428740468, COSV64767426, COSV64767953; called by muse, mutect2, varscan2
- KDM6B | c.2324T>C p.L775P | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.854); catalogued as rs758101438; called by muse, varscan2
- KDM8 | c.799-2A>G p.X267_splice | Splice Site (SNP) | VAF 17/219 reads (8%) | catalogued as COSV53728372; called by muse, mutect2
- KIAA0232 | c.3785C>T p.S1262L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.995); catalogued as rs369418898; called by muse, mutect2, varscan2
- KIAA1549 | c.3869C>T p.P1290L | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs984290862, COSV54320636; called by muse, mutect2, varscan2
- KIAA1549 | c.848del p.L283* | Frame Shift Del (DEL) | VAF 40/221 reads (18%) | catalogued as rs752375544, COSV54318481; called by mutect2, pindel, varscan2
- KIF18B | c.1900G>A p.A634T (on ENST00000593135 / NM_001265577.2; = p.A646T on NM_001264573.2) | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs762699986, COSV100192148; called by mutect2, varscan2
- KIF26A | c.2618G>A p.R873Q | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.285); catalogued as rs1266912265; called by muse, mutect2, varscan2
- KIF26B | c.3032C>T p.A1011V | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs767436618, COSV63636206; called by muse, mutect2, varscan2
- KIF26B | c.3823C>T p.R1275C | Missense Mutation (SNP) | VAF 37/363 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs199597747; called by muse, mutect2, varscan2
- KIF5C | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1222200321; called by muse, mutect2, varscan2
- KIFC3 | c.1171G>A p.G391S | Missense Mutation (SNP) | VAF 44/307 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs782747205, COSV65551685; called by muse, mutect2, varscan2
- KIRREL1 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs201328955; called by muse, mutect2, varscan2
- KLC2 | c.1700del p.G567Afs*11 | Frame Shift Del (DEL) | VAF 21/149 reads (14%) | catalogued as rs772643711; called by mutect2, pindel, varscan2
- KLF9 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs1292843135; called by muse, varscan2
- KMT2D | c.15958C>T p.R5320C | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1469731570, COSV56421612; called by muse, mutect2, varscan2
- KMT5C | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs866476245; called by muse, mutect2, varscan2
- KNDC1 | c.2603G>A p.R868Q | Missense Mutation (SNP) | VAF 69/313 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs367837569, COSV100466080; called by muse, mutect2, varscan2
- KRT13 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.607); catalogued as rs140888301; called by muse, mutect2, varscan2
- KRT20 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs553162264, COSV51425044; called by muse, mutect2, varscan2
- KRT34 | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 56/238 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as rs754757891, COSV67450018; called by muse, mutect2, varscan2
- KRT79 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 43/293 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.14); catalogued as rs376128731; called by muse, mutect2, varscan2
- KTN1 | c.3192G>T p.Q1064H (on ENST00000395314 / NM_001271014.2; = p.Q1035H on NM_004986.4) | Missense Mutation (SNP) | VAF 50/334 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV58539888; called by muse, mutect2, varscan2
- LAMA5 | c.9633G>A p.T3211= | Splice Region (SNP) | VAF 18/85 reads (21%) | catalogued as rs760388258; called by muse, mutect2, varscan2
- LAMB2 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 42/462 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.146); catalogued as rs761845975; called by muse, mutect2
- LAMB3 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 105/570 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.788); catalogued as rs549692468, CD031511, COSV61916357; called by muse, mutect2, varscan2
- LAMB3 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs145575474, COSV61916499, COSV61918706; called by muse, mutect2, varscan2
- LCA5 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 31/184 reads (17%) | catalogued as rs151017794, CM1312837; called by muse, mutect2, varscan2
- LCA5L | c.467del p.N156Mfs*3 | Frame Shift Del (DEL) | VAF 9/78 reads (12%) | catalogued as rs747213855; called by mutect2, pindel, varscan2
- LDB1 | c.772C>T p.R258C (on ENST00000425280 / NM_001321612.2; = p.R222C on NM_003893.5) | Missense Mutation (SNP) | VAF 64/338 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV104419392; called by muse, mutect2, varscan2
- LENG8 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); catalogued as rs775864281; called by muse, mutect2, varscan2
- LGALS9 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 64/376 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.034); catalogued as rs777812677; called by muse, mutect2, varscan2
- LGMN | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs771834504, COSV58405338; called by muse, mutect2, varscan2
- LGSN | c.896T>C p.I299T | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as rs749055919; called by muse, mutect2, varscan2
- LHFPL5 | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 67/450 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs766245505, COSV100798931, COSV64178172; called by muse, mutect2, varscan2
- LINGO1-AS1 | n.317C>T | Splice Region (SNP) | VAF 8/58 reads (14%) | catalogued as rs776158654; called by muse, mutect2
- LIPC | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 95/594 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs573111255, COSV54421967; called by muse, mutect2, varscan2
- LMTK2 | c.1393G>A p.V465M | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1291773145, COSV51990952; called by muse, mutect2, varscan2
- LOXL1 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 58/340 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs566197761, COSV56093456; called by muse, mutect2, varscan2
- LRBA | c.8257C>T p.H2753Y | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.265); catalogued as rs200580681; called by muse, mutect2, varscan2
- LRRC15 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 77/424 reads (18%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as rs766176026; called by muse, mutect2, varscan2
- LRRC56 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs560844721, COSV54238803; called by muse, mutect2, varscan2
- LRRC9 | c.3853C>T p.R1285* | Nonsense Mutation (SNP) | VAF 22/179 reads (12%) | catalogued as rs1467701623; called by muse, varscan2
- LRRN4 | c.2042C>T p.A681V | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV66645678; called by muse, mutect2
- LRTM2 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 57/372 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs149305538; called by muse, mutect2, varscan2
- LRWD1 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 61/293 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs535806746; called by muse, mutect2, varscan2
- LTBP1 | c.5089G>A p.V1697M (on ENST00000404816 / NM_206943.4; = p.V1371M on NM_000627.4) | Missense Mutation (SNP) | VAF 47/261 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.734); catalogued as rs770536450, COSV55385331, COSV99698140; called by muse, mutect2, varscan2
- LZTR1 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as rs935736801, COSV53151511; called by muse, mutect2, varscan2
- MAG | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.248); catalogued as COSV62699573; called by muse, mutect2, varscan2
- MAGI1 | c.4295C>T p.A1432V | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1474945715; called by muse, mutect2, varscan2
- MAN1A2 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as rs751342547; called by muse, mutect2
- MAP1B | c.2429C>T p.A810V | Missense Mutation (SNP) | VAF 44/398 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs759856336, COSV57102245; called by muse, mutect2, varscan2
- MAP2K3 | c.215G>A p.R72H (on ENST00000342679 / NM_145109.3; = p.R43H on NM_002756.4) | Missense Mutation (SNP) | VAF 49/465 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs747410898, COSV57567355; called by muse, mutect2, varscan2
- MARCHF4 | c.258del p.W87Gfs*72 | Frame Shift Del (DEL) | VAF 17/84 reads (20%) | catalogued as rs1559109946; called by mutect2, pindel, varscan2
- MARCHF6 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 49/235 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs745896413; called by muse, mutect2, varscan2
- MAST2 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 52/307 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs754387096; called by muse, mutect2, varscan2
- MAST2 | c.4082G>A p.R1361Q | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.772); catalogued as rs758094340; called by muse, mutect2, varscan2
- MBTPS2 | c.384_407del p.S129_S136del | In Frame Del (DEL) | VAF 50/298 reads (17%) | catalogued as rs761369288; called by mutect2, varscan2*
- MCCC1 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs727504004, CM053306, COSV55610531; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MDGA1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 78/500 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.838); catalogued as rs368289358, COSV99777151; called by muse, mutect2, varscan2
- MDH2 | c.704C>T p.T235M | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs368008244; called by muse, mutect2, varscan2
- MDM1 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs539072155; called by muse, mutect2, varscan2
- MED1 | c.2029C>T p.R677C | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs770651048; called by muse, mutect2, varscan2
- MED12L | c.3374C>T p.A1125V | Missense Mutation (SNP) | VAF 41/314 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1472677463, COSV56399486; called by muse, mutect2, varscan2
- MED26 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs752977684; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 25/184 reads (14%) | catalogued as rs745558596; called by mutect2, pindel, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 17/132 reads (13%) | catalogued as rs762115034; called by mutect2, pindel, varscan2
- MFSD10 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 80/625 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754386132; called by muse, mutect2, varscan2
- MFSD10 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as rs201068903, COSV53266000; called by muse, mutect2, varscan2
- MFSD14A | c.1124C>T p.T375I | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776210415; called by muse, mutect2, varscan2
- MGA | c.8581C>T p.R2861W (on ENST00000219905 / NM_001164273.1; = p.R2652W on NM_001080541.2) | Missense Mutation (SNP) | VAF 47/301 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs749267770, COSV54948011; called by muse, mutect2, varscan2
- MGST2 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.494); catalogued as rs770784272; called by muse, mutect2, varscan2
- MIER3 | c.1027del p.R343Dfs*15 (on ENST00000381199 / NM_001297599.2; = p.R342Dfs*15 on NM_152622.4) | Frame Shift Del (DEL) | VAF 24/130 reads (18%) | catalogued as COSV67083276; called by mutect2, pindel, varscan2
- MINDY1 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.926); catalogued as rs769593812, COSV56500102; called by muse, mutect2, varscan2
- MITF | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 13/284 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58886485; called by muse, mutect2
- MKRN1 | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.282); catalogued as rs1062778; called by muse, mutect2, varscan2
- MMP12 | c.922C>A p.L308M | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs1384924559; called by muse, mutect2, varscan2
- MMP24 | c.1483C>T p.R495W | Missense Mutation (SNP) | VAF 80/469 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as rs746247860, COSV55768875; called by muse, mutect2, varscan2
- MMP25 | c.1386del p.S463Pfs*97 | Frame Shift Del (DEL) | VAF 32/143 reads (22%) | catalogued as rs1328316597; called by mutect2, pindel, varscan2
- MOCOS | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 50/308 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370660891, COSV99733184; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 24/214 reads (11%) | catalogued as rs755830405; called by mutect2, varscan2
- MPST | c.571G>A p.G191S (on ENST00000341116 / NM_001369904.2; = p.G211S on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/284 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs910259100, COSV62018379; called by muse, mutect2, varscan2
- MRGPRE | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.737); catalogued as rs555203753, COSV101099954; called by muse, mutect2, varscan2
- MROH9 | c.2353C>T p.R785* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as rs748211477; called by muse, mutect2, varscan2
- MRPS5 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs548833325, COSV55535400; called by muse, mutect2, varscan2
- MSH2 | c.1600del p.R534Vfs*9 | Frame Shift Del (DEL) | VAF 23/189 reads (12%) | catalogued as CS068444, COSV51877993, COSV51879680; called by mutect2, pindel, varscan2
- MSH2 | c.2704G>T p.E902* | Nonsense Mutation (SNP) | VAF 40/189 reads (21%) | catalogued as rs867671639, COSV99253103; called by muse, mutect2, varscan2
- MSH3 | c.3335C>T p.T1112M | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs576204286, COSV54148749; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTCL1 | c.4520C>T p.S1507L (on ENST00000306329 / NM_001378206.1; = p.S1188L on NM_015210.4) | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs1198889117; called by muse, mutect2
- MTHFR | c.1780C>T p.R594W | Missense Mutation (SNP) | VAF 58/480 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as rs775066323; called by muse, mutect2, varscan2
- MTHFSD | c.1003C>T p.R335W (on ENST00000360900 / NM_001159377.2; = p.R334W on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs747084274; called by muse, mutect2, varscan2
- MTOR | c.5453G>A p.R1818H | Missense Mutation (SNP) | VAF 89/550 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs563143860; called by muse, mutect2, varscan2
- MTR | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 49/297 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs780526997; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTSS1 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1197259244, COSV52674472; called by muse, mutect2, varscan2
- MXD3 | c.148del p.Q50Rfs*24 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | catalogued as rs866699857; called by mutect2, varscan2
- MYBL1 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs373512999; called by muse, mutect2, varscan2
- MYH1 | c.4436G>A p.R1479H | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs376070618, COSV56846383; called by muse, mutect2, varscan2
- MYO10 | c.3674del p.G1225Afs*22 | Frame Shift Del (DEL) | VAF 105/549 reads (19%) | catalogued as rs760302326; called by mutect2, varscan2
- MYO1C | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.998); catalogued as rs561446989; called by muse, mutect2, varscan2
- MYO1E | c.3274C>T p.R1092* | Nonsense Mutation (SNP) | VAF 81/458 reads (18%) | catalogued as rs757880374; called by muse, mutect2, varscan2
- MYO3B | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100511383; called by muse, mutect2
- MYO9B | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 71/359 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs770104097; called by muse, mutect2, varscan2
- MYO9B | c.1991G>A p.R664Q | Missense Mutation (SNP) | VAF 104/533 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772454469, COSV68276649; called by muse, mutect2, varscan2
- MYOM2 | c.1790C>T p.S597L | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766631002; called by muse, mutect2, varscan2
- MYRIP | c.1645C>T p.R549W | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs769963893, COSV56881847; called by mutect2, varscan2
- MZF1 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 91/587 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs759875440; called by muse, mutect2, varscan2
- N4BP2 | c.4949del p.N1650Mfs*17 | Frame Shift Del (DEL) | VAF 28/165 reads (17%) | catalogued as rs763929397; called by mutect2, varscan2
- NAPEPLD | c.842del p.F281Sfs*14 | Frame Shift Del (DEL) | VAF 70/396 reads (18%) | catalogued as rs746683932, COSV100439928; called by mutect2, varscan2
- NAPRT | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.232); catalogued as rs771976733; called by muse, mutect2, varscan2
- NAV2 | c.4816C>T p.R1606C (on ENST00000396087 / NM_001244963.2; = p.R1583C on NM_145117.5) | Missense Mutation (SNP) | VAF 44/290 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs202118914; called by muse, mutect2, varscan2
- NBPF26 | c.4122G>T p.M1374I (on ENST00000620612; = p.M1112I on NM_001351372.1) | Missense Mutation (SNP) | VAF 67/284 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.733); catalogued as rs1553273422; called by muse, mutect2, varscan2
- NCAN | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs139539812; called by muse, mutect2
- NCDN | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.446); catalogued as rs752708609, COSV61934916; called by muse, mutect2, varscan2
- NCOA5 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs768417079; called by muse, mutect2, varscan2
- NDUFA11 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as rs773239975; called by muse, mutect2, varscan2
- NEK7 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66314751, COSV66315611; called by muse, mutect2, varscan2
- NEURL1B | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV100874829; called by muse, varscan2
- NFIB | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66621081; called by muse, mutect2, varscan2
- NFIC | c.1490C>T p.A497V (on ENST00000443272 / NM_001245002.2; = p.A488V on NM_205843.3) | Missense Mutation (SNP) | VAF 31/293 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as rs768921539; called by muse, mutect2, varscan2
- NFX1 | c.3092G>A p.R1031H | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765481026; called by muse, varscan2
- NGDN | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.105); catalogued as rs373213437; called by muse, mutect2, varscan2
- NKAP | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV65055972; called by muse, mutect2, varscan2
- NLGN3 | c.2167G>A p.V723I (on ENST00000358741 / NM_181303.2; = p.V703I on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/364 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs773087233, COSV62445592; called by muse, mutect2, varscan2
- NMRAL1 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 86/508 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.949); catalogued as rs375090595; called by muse, mutect2, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 39/253 reads (15%) | catalogued as rs749517498, COSV52496454; called by mutect2, varscan2
- NOS3 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 58/255 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs765169676, COSV52486396, COSV52492850, COSV52495663; called by muse, mutect2, varscan2
- NPAS1 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs760316058, COSV71383872; called by muse, mutect2, varscan2
- NPAS3 | c.1766C>T p.A589V (on ENST00000356141 / NM_001164749.2; = p.A557V on NM_022123.3) | Missense Mutation (SNP) | VAF 72/467 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs770665316, COSV100640213; called by muse, mutect2, varscan2
- NPC1L1 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 40/273 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs199897840; called by muse, mutect2, varscan2
- NPIPB4 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 51/706 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.223); catalogued as rs772684976, COSV51254561; called by muse, varscan2
- NPNT | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 56/330 reads (17%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.475); catalogued as rs1195787704; called by muse, mutect2, varscan2
- NPR2 | c.2987C>T p.A996V | Missense Mutation (SNP) | VAF 54/315 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs143187530; called by muse, mutect2, varscan2
- NQO2 | c.171T>G p.T57= | Splice Region (SNP) | VAF 23/102 reads (23%) | catalogued as rs1220311743; called by muse, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 17/112 reads (15%) | catalogued as rs774343392; called by mutect2, varscan2
- NRCAM | c.3467C>T p.A1156V (on ENST00000379028 / NM_001371124.1; = p.A1035V on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs755405364; called by muse, mutect2, varscan2
- NRG3 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.91); catalogued as rs746149176, COSV64572664; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 24/136 reads (18%) | catalogued as rs776154715; called by mutect2, varscan2
- NRXN2 | c.3899G>A p.R1300Q | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs760897904, COSV55456161; called by muse, mutect2
- NTN4 | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 15/151 reads (10%) | catalogued as rs757810418; called by muse, mutect2, varscan2
- NTRK1 | c.772C>A p.L258I | Missense Mutation (SNP) | VAF 48/313 reads (15%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.996); catalogued as COSV62324353; called by muse, mutect2, varscan2
- NUAK2 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.27); catalogued as rs374096584; called by muse, mutect2, varscan2
- NUP107 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 44/267 reads (16%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as rs146283576; called by muse, mutect2, varscan2
- NUP85 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs371512162; called by muse, mutect2, varscan2
- NYAP2 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.267); catalogued as COSV56001420; called by muse, varscan2
- NYAP2 | c.1499del p.G500Vfs*15 | Frame Shift Del (DEL) | VAF 69/493 reads (14%) | catalogued as COSV56002002; called by pindel, varscan2
- OBSL1 | c.4783C>T p.R1595* | Nonsense Mutation (SNP) | VAF 55/396 reads (14%) | catalogued as rs200174777; called by muse, mutect2, varscan2
- OGT | c.2527G>A p.V843I | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.063); catalogued as COSV65481873, COSV65482220; called by muse, mutect2, varscan2
- OLFM1 | c.1315G>A p.D439N (on ENST00000371793 / NM_001282611.2; = p.D421N on NM_014279.5) | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs895515163, COSV53281583; called by muse, mutect2, varscan2
- OPRD1 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.053); catalogued as COSV104376046; called by muse, mutect2, varscan2
- OR1E2 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 50/304 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as rs371695952; called by muse, mutect2, varscan2
- OR2F1 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 27/143 reads (19%) | catalogued as rs771184781, COSV67331747; called by muse, mutect2, varscan2
- OR4C46 | c.90dup p.V31Cfs*38 | Frame Shift Ins (INS) | VAF 36/267 reads (13%) | catalogued as rs759167019; called by mutect2, pindel, varscan2
- OR52B2 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as rs576479650, COSV101603946, COSV101603947; called by muse, mutect2, varscan2
- OR7C1 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.15); catalogued as rs1049317748, COSV99934916; called by muse, mutect2, varscan2
- OSBPL2 | c.217G>A p.D73N (on ENST00000313733 / NM_144498.4; = p.D61N on NM_014835.4) | Missense Mutation (SNP) | VAF 55/362 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs780010928; called by muse, mutect2, varscan2
- OSBPL5 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as rs143909358; called by muse, varscan2
- OTOG | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 71/373 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs1051708966, COSV68038596; called by muse, mutect2, varscan2
- OVOL2 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); catalogued as rs762166610; called by muse, mutect2
- OXCT1 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 62/334 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs755989003, COSV52166822; called by muse, mutect2, varscan2
- PAMR1 | c.302del p.G101Vfs*8 | Frame Shift Del (DEL) | VAF 21/150 reads (14%) | catalogued as rs751755759; called by mutect2, pindel, varscan2
- PAPPA2 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 48/295 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs548559188, COSV62787700; called by muse, mutect2, varscan2
- PAX1 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 58/376 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68271634; called by muse, mutect2, varscan2
- PCDH11X | c.2971G>A p.V991I | Missense Mutation (SNP) | VAF 102/569 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.044); catalogued as rs373159801; called by muse, mutect2, varscan2
- PCDH17 | c.1223del p.G408Vfs*18 | Frame Shift Del (DEL) | VAF 48/386 reads (12%) | catalogued as COSV64974164; called by pindel, varscan2
- PCDH17 | c.1370C>T p.S457L | Missense Mutation (SNP) | VAF 74/439 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1460461490; called by muse, varscan2
- PCDHA11 | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 114/560 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.021); catalogued as rs782454963, COSV56484438; called by muse, mutect2, varscan2
- PCDHA12 | c.1342G>A p.V448M | Missense Mutation (SNP) | VAF 122/704 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as rs571648883, COSV56475315; called by muse, mutect2, varscan2
- PCDHA13 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.017); catalogued as rs1554176457, COSV56506842; called by muse, mutect2, varscan2
- PCDHA13 | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 60/308 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.055); catalogued as rs139927854; called by muse, mutect2, varscan2
- PCDHA9 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 112/558 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.287); catalogued as rs199864758, COSV65330932; called by muse, mutect2, varscan2
- PCDHB2 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 72/450 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99165790; called by mutect2, varscan2
- PCDHB8 | c.1591C>T p.R531W | Missense Mutation (SNP) | VAF 163/998 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.86); catalogued as rs781850313, COSV50758133; called by muse, mutect2, varscan2
- PCDHGA12 | c.1795G>A p.G599S | Missense Mutation (SNP) | VAF 92/527 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs757821109; called by muse, mutect2, varscan2
- PCDHGA2 | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 92/548 reads (17%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.006); catalogued as rs769248665, COSV53929048; called by muse, mutect2, varscan2
- PCDHGA3 | c.1636G>A p.V546M | Missense Mutation (SNP) | VAF 83/559 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.378); catalogued as COSV53938956; called by muse, mutect2, varscan2
- PCDHGA9 | c.81G>T p.R27S | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.01); catalogued as rs764461706; called by muse, mutect2, varscan2
- PCMTD2 | c.1037C>A p.P346H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55059954; called by muse, varscan2
- PCNX3 | c.2305C>T p.R769C | Missense Mutation (SNP) | VAF 53/333 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs1246132115; called by muse, mutect2, varscan2
- PCNX3 | c.4441C>T p.R1481C | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV63135563; called by muse, mutect2
- PDE1B | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.079); catalogued as rs1350794251; called by muse, mutect2, varscan2
- PDE8A | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1274686948, COSV59635311; called by muse, mutect2, varscan2
- PDGFB | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 46/309 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs779509116; called by muse, mutect2, varscan2
- PDS5A | c.3814C>T p.R1272C | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs1222220142, COSV57826983; called by muse, mutect2, varscan2
- PDSS1 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.009); catalogued as rs778744862; called by muse, mutect2, varscan2
- PDZD2 | c.4814G>A p.R1605H | Missense Mutation (SNP) | VAF 35/236 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs368453520; called by muse, mutect2, varscan2
- PELI3 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 55/280 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs756626915; called by muse, mutect2, varscan2
- PEX14 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 118/637 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs200019568; called by muse, mutect2, varscan2
- PFKFB2 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 15/118 reads (13%) | PolyPhen possibly damaging (0.894); catalogued as rs757942412, COSV65547271; called by muse, mutect2, varscan2
- PFKFB3 | c.1262C>T p.T421M | Missense Mutation (SNP) | VAF 44/273 reads (16%) | PolyPhen probably damaging (0.96); catalogued as rs747166742, COSV57992172; called by muse, mutect2, varscan2
- PFKP | c.2264G>A p.R755Q | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs141623019; called by muse, mutect2, varscan2
- PGAM1 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 63/574 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.3); catalogued as rs1180971119; called by muse, mutect2, varscan2
- PGBD5 | c.1301G>A p.R434Q (on ENST00000525115; = p.R503Q on NM_001258311.2) | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.992); catalogued as rs1448260127, COSV58413634; called by muse, mutect2, varscan2
- PGGHG | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 59/334 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs929224841; called by muse, mutect2, varscan2
- PGPEP1L | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 139/801 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.883); catalogued as rs761032396, COSV100967265; called by muse, mutect2, varscan2
- PGRMC1 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 54/331 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs769632512, COSV54293545; called by muse, mutect2, varscan2
- PHKA2 | c.2180G>A p.R727H | Missense Mutation (SNP) | VAF 84/480 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as rs1324708505; called by muse, varscan2
- PHRF1 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs375767361; called by muse, mutect2
- PIK3C2A | c.4862C>T p.P1621L | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751396589; called by muse, mutect2, varscan2
- PKD1 | c.7406G>A p.R2469H | Missense Mutation (SNP) | VAF 90/431 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as rs770918119; called by muse, mutect2, varscan2
- PKD1 | c.5891G>A p.R1964H | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs754379960; called by muse, mutect2, varscan2
- PKD1 | c.3736G>A p.D1246N | Missense Mutation (SNP) | VAF 56/853 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as rs553360241, COSV51919527; ClinVar: uncertain significance; called by muse, mutect2
- PKHD1 | c.11869C>T p.R3957C | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.451); catalogued as rs146680689, CM100416; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCB4 | c.2164G>A p.V722I | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs772944610, COSV53796321, COSV99059197; called by muse, mutect2
- PLEC | c.11338G>A p.V3780M (on ENST00000322810 / NM_201380.4; = p.V3670M on NM_000445.5) | Missense Mutation (SNP) | VAF 144/868 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as rs372569386, COSV59656791, COSV59713768; called by muse, mutect2
- PLEC | c.2680G>A p.V894I (on ENST00000322810 / NM_201380.4; = p.V784I on NM_000445.5) | Missense Mutation (SNP) | VAF 138/675 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs782595372, COSV59689182; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHH3 | c.574del p.V192Wfs*6 | Frame Shift Del (DEL) | VAF 26/160 reads (16%) | catalogued as rs778393033; called by mutect2, pindel, varscan2
- PLEKHN1 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 51/244 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs752465994; called by muse, mutect2, varscan2
- PLPP4 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367975027; called by muse, mutect2, varscan2
- PLPPR2 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs776782767; called by mutect2, varscan2
- PLXNA1 | c.3160G>A p.D1054N | Missense Mutation (SNP) | VAF 43/255 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs1162492330; called by muse, mutect2, varscan2
- PLXNA1 | c.4693C>T p.R1565C | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745655858, COSV52526771; called by muse, mutect2, varscan2
- POGLUT2 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs776597327; called by muse, mutect2, varscan2
- POLB | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 45/283 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs766919977, COSV55183675; called by muse, mutect2, varscan2
- POLG | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 86/423 reads (20%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV51520543; called by muse, varscan2
- POLQ | c.6953T>C p.F2318S | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51752456; called by muse, mutect2, varscan2
- POLR1A | c.1999C>T p.R667C | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs548777142; called by muse, mutect2, varscan2
- POLR3B | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 59/399 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.529); catalogued as rs746506474, COSV57276297; called by muse, mutect2, varscan2
- POMT1 | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 23/709 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs1174599967; called by muse, mutect2
- POU3F2 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 68/347 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60409371; called by muse, mutect2, varscan2
- PPIE | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as rs758313497, COSV60971602; called by muse, mutect2, varscan2
- PRAG1 | c.3730G>A p.V1244M | Missense Mutation (SNP) | VAF 42/319 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as COSV58162801; called by muse, mutect2, varscan2
- PRAM1 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs750944789; called by muse, varscan2
- PRF1 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs140385034; called by muse, mutect2, varscan2
- PRKD1 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 70/345 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs768104173; called by muse, mutect2, varscan2
- PRKG2 | c.1042del p.T348Hfs*35 | Frame Shift Del (DEL) | VAF 32/254 reads (13%) | catalogued as rs753019548; called by pindel, varscan2
- PROSER3 | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 54/266 reads (20%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.514); catalogued as rs772306285; called by muse, mutect2, varscan2
- PRPF31 | c.527+8C>T | Splice Region (SNP) | VAF 82/442 reads (19%) | catalogued as rs747332626; called by muse, mutect2, varscan2
- PRR19 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.549); catalogued as rs781493391, COSV56627393; called by muse, mutect2, varscan2
- PRR23B | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV61493538; called by muse, mutect2, varscan2
- PRRC2A | c.2213G>A p.R738H | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1434089713; called by muse, mutect2, varscan2
- PRSS36 | c.736C>G p.P246A | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761384505, COSV51637384; called by muse, mutect2, varscan2
- PRSS54 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs367701903; called by muse, mutect2
- PSD | c.750del p.S251Afs*43 | Frame Shift Del (DEL) | VAF 11/79 reads (14%) | catalogued as rs761494960; called by mutect2, pindel
- PTCH1 | c.1218G>A p.V406= | Splice Region (SNP) | VAF 53/425 reads (12%) | catalogued as rs753586235; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTHLH | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 35/242 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.027); catalogued as rs976794916, COSV52367468; called by muse, mutect2, varscan2
- PTPN13 | c.855del p.K285Nfs*45 | Frame Shift Del (DEL) | VAF 26/188 reads (14%) | catalogued as rs754278242; called by mutect2, varscan2
- PTPRF | c.3544C>T p.R1182C | Missense Mutation (SNP) | VAF 58/344 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.326); catalogued as rs1037410695; called by muse, mutect2, varscan2
- PTPRJ | c.2786G>A p.R929Q | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772518466, COSV101395232; called by muse, mutect2, varscan2
- PTPRK | c.3991C>T p.Q1331* (on ENST00000368215 / NM_001291984.2; = p.Q1332* on NM_002844.4) | Nonsense Mutation (SNP) | VAF 21/138 reads (15%) | catalogued as rs762155610; called by muse, mutect2, varscan2
- PTPRS | c.3072del p.V1025Sfs*18 | Frame Shift Del (DEL) | VAF 28/177 reads (16%) | catalogued as rs756013055, COSV53629833; called by mutect2, pindel, varscan2
- PWWP2B | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 53/343 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs911653247; called by muse, mutect2, varscan2
- PXDN | c.2870C>T p.T957M | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); catalogued as COSV53248812; called by muse, mutect2, varscan2
- PXDNL | c.2399C>T p.T800M | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62481105; called by muse, mutect2
- PXN | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 69/458 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375121495; called by muse, mutect2, varscan2
- PYCR2 | c.885del p.T296Qfs*5 | Frame Shift Del (DEL) | VAF 23/118 reads (19%) | catalogued as rs1383249693; called by mutect2, pindel, varscan2
- QRICH2 | c.1715G>A p.R572H | Missense Mutation (SNP) | VAF 90/538 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs756202185; called by muse, mutect2, varscan2
- RAB18 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 59/292 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs140686479; called by muse, mutect2, varscan2
- RABEP1 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764364995; called by muse, mutect2, varscan2
- RABGAP1 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs536606696, COSV65394653; called by muse, mutect2, varscan2
- RAD23A | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as rs748795390, COSV57119644; called by muse, mutect2, varscan2
- RAD54B | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as rs534637551; called by muse, mutect2
- RAG2 | c.1496del p.K499Sfs*4 | Frame Shift Del (DEL) | VAF 68/411 reads (17%) | catalogued as rs1251406873; called by mutect2, varscan2
- RALGAPA2 | c.2754del p.S919Afs*24 | Frame Shift Del (DEL) | VAF 33/214 reads (15%) | catalogued as COSV99173620; called by mutect2, pindel, varscan2
- RANBP3 | c.1473G>A p.S491= (on ENST00000340578 / NM_007322.3; = p.S486= on NM_003624.3) | Splice Region (SNP) | VAF 30/148 reads (20%) | catalogued as rs1012413726, COSV50382238; called by muse, mutect2, varscan2
- RASAL3 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 60/348 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768290742; called by muse, mutect2, varscan2
- RBBP7 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.154); catalogued as COSV58112635; called by muse, mutect2, varscan2
- RBBP8 | c.1071del p.K357Nfs*3 | Frame Shift Del (DEL) | VAF 28/183 reads (15%) | catalogued as rs754547584, COSV59093143; ClinVar: uncertain significance; called by mutect2, varscan2
- RBFOX3 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1208480613; called by muse, mutect2, varscan2
- RBL2 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 27/134 reads (20%) | catalogued as COSV50881667; called by muse, mutect2, varscan2
- RBM33 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0.009); catalogued as rs758201933, COSV100265094; called by muse, mutect2, varscan2
- RBM33 | c.3089del p.G1030Afs*52 | Frame Shift Del (DEL) | VAF 29/176 reads (16%) | catalogued as COSV62031451; called by mutect2, pindel, varscan2
- RBM4 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs771127066; called by muse, mutect2, varscan2
- RET | c.1783G>C p.E595Q | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.955); catalogued as rs1483605155, CM1111630, CS1110912, COSV60693777; called by muse, mutect2, varscan2
- RFNG | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.106); catalogued as rs372993379; called by muse, mutect2, varscan2
- RFPL4A | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 64/762 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.824); catalogued as rs1433080705, COSV70455773; called by muse, mutect2
- RFT1 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 98/518 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.057); catalogued as rs781398694, COSV56248229; called by muse, mutect2, varscan2
- RGPD1 | c.1336C>T p.R446* (on ENST00000409776; = p.R454* on NM_001024457.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/106 reads (12%) | catalogued as rs1348576710; called by mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 16/94 reads (17%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | catalogued as rs751982308; called by mutect2, varscan2
- RGS8 | c.227C>T p.T76M (on ENST00000367556 / NM_001369564.2; = p.T94M on NM_033345.3) | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs759655284, COSV99276455; called by muse, mutect2
- RIMBP2 | c.2470G>A p.D824N | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as COSV55481960; called by muse, mutect2, varscan2
- RIPK4 | c.1987G>A p.G663R (on ENST00000352483; = p.G615R on NM_020639.3) | Missense Mutation (SNP) | VAF 60/233 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773928153, COSV60191799; called by muse, mutect2, varscan2
- RIPK4 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 55/294 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs759682809, COSV100205083; called by muse, mutect2, varscan2
- RIPOR3 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 50/322 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779249727, COSV99246176; called by muse, mutect2, varscan2
- RNASE4 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 43/250 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs374269522, COSV59011986; called by muse, mutect2, varscan2
- RNF112 | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs377199559; called by muse, mutect2, varscan2
- RNF20 | c.2845C>T p.R949C | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101206588; called by muse, mutect2, varscan2
- RNF222 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.393); catalogued as rs1247979744; called by muse, mutect2, varscan2
- RNF44 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775671022; called by muse, mutect2, varscan2
- RNPEPL1 | c.616_618del p.F206del | In Frame Del (DEL) | VAF 60/369 reads (16%) | catalogued as rs1559415768; called by pindel, varscan2
- ROR2 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 83/439 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs746196217, COSV65219329; called by muse, mutect2, varscan2
- RPS6KB2 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199664699, COSV100396663; called by muse, mutect2, varscan2
- RPTOR | c.3772G>A p.A1258T | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as rs751407036; called by muse, mutect2, varscan2
- RTL1 | c.2581C>T p.R861C | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs1457336557; called by muse, varscan2
- RTL1 | c.2269C>T p.R757C | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs891986142; called by muse, mutect2, varscan2
- RTTN | c.5744del p.K1915Rfs*9 | Frame Shift Del (DEL) | VAF 21/156 reads (13%) | catalogued as rs756606313; called by mutect2, varscan2
- RUNX1 | c.818C>T p.T273M (on ENST00000344691 / NM_001001890.3; = p.T300M on NM_001754.5) | Missense Mutation (SNP) | VAF 41/354 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs758682659, COSV55866372; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RUNX1T1 | c.1118G>A p.R373Q (on ENST00000265814 / NM_001198628.1; = p.R346Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/433 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554604800, COSV56147226; called by muse, mutect2, varscan2
- RYK | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV56060568; called by muse, mutect2, varscan2
- SAFB | c.2512G>A p.D838N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as rs370175216; called by muse, mutect2, varscan2
- SAMD9L | c.4540A>G p.K1514E | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.204); catalogued as rs773710761, COSV59080075, COSV59080638; called by muse, mutect2, varscan2
- SAR1B | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as rs749648549, CM1210278; called by muse, mutect2
- SART1 | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 60/272 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs961544168; called by muse, mutect2, varscan2
- SART3 | c.1769G>A p.R590Q (on ENST00000228284; = p.R572Q on NM_014706.4) | Missense Mutation (SNP) | VAF 54/380 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.397); catalogued as rs1349043518, COSV57206879; called by muse, mutect2, varscan2
- SAXO1 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 63/324 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as rs117915008, COSV65871799; called by muse, mutect2, varscan2
- SBNO2 | c.3517C>T p.R1173C | Missense Mutation (SNP) | VAF 95/508 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1220589800; called by muse, mutect2, varscan2
- SCAF1 | c.1807C>T p.R603W | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.312); catalogued as rs1005911582; called by muse, mutect2, varscan2
- SCAF11 | c.2947C>T p.R983W | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs377258916; called by muse, mutect2, varscan2
- SCN5A | c.5795C>T p.A1932V (on ENST00000333535 / NM_198056.3; = p.A1931V on NM_000335.5) | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs371194826; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SCN9A | c.5157del p.V1720Ffs*33 (on ENST00000303354; = p.V1709Ffs*33 on NM_002977.3) | Frame Shift Del (DEL) | VAF 39/249 reads (16%) | catalogued as rs1027061303; called by mutect2, pindel, varscan2
- SDCCAG8 | c.416G>A p.C139Y | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs773522256; called by muse, mutect2, varscan2
- SEC16B | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs765443077; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 65/173 reads (38%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEC31A | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs781481399; called by muse, mutect2, varscan2
- SEMA3F | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs756396183; called by muse, mutect2, varscan2
- SEMA6A | c.3014C>T p.S1005L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1401123283, COSV56710053; called by muse, mutect2, varscan2
- SEPTIN3 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1008009421; called by muse, mutect2, varscan2
- SERTAD2 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 45/244 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as rs760972379, COSV57640348; called by muse, mutect2, varscan2
- SETDB2 | c.2152del p.I718Yfs*11 | Frame Shift Del (DEL) | VAF 23/204 reads (11%) | catalogued as rs775302281, COSV57902985; called by mutect2, varscan2
- SFRP4 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs775432602, COSV71412432; called by muse, mutect2, varscan2
- SFRP5 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs144307831; called by muse, mutect2, varscan2
- SH3TC1 | c.3899_3901del p.F1300del | In Frame Del (DEL) | VAF 110/611 reads (18%) | catalogued as rs767735149; called by pindel, varscan2
- SHANK1 | c.4643C>T p.P1548L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777740266; called by muse, mutect2, varscan2
- SHANK2 | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs557890906; called by muse, mutect2, varscan2
- SIX3 | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 43/202 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53226763; called by muse, mutect2, varscan2
- SIX6 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 70/399 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1376068996, COSV59802122; called by muse, mutect2, varscan2
- SKIDA1 | c.1867_1869del p.N623del | In Frame Del (DEL) | VAF 22/122 reads (18%) | catalogued as rs1231524277; called by pindel, varscan2
- SLC12A1 | c.2628del p.D877Mfs*46 | Frame Shift Del (DEL) | VAF 16/99 reads (16%) | catalogued as rs1419151341, COSV66797187; called by mutect2, pindel, varscan2
- SLC14A2 | c.1492C>T p.H498Y | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1568000915; called by muse, mutect2, varscan2
- SLC1A3 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 78/422 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1038146073, COSV54317019, COSV54320645; called by muse, mutect2, varscan2
- SLC25A29 | c.680G>A p.R227H (on ENST00000359232 / NM_001039355.3; = p.R161H on NM_152333.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/497 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV63650455; called by muse, mutect2, varscan2
- SLC25A48 | c.908G>A p.R303H (on ENST00000650267; = p.A253T on NM_001349335.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs754995493, COSV69698080; called by muse, varscan2
- SLC26A8 | c.2573C>T p.S858L | Missense Mutation (SNP) | VAF 54/341 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs758509513; called by muse, mutect2, varscan2
- SLC2A6 | c.425C>T p.T142M | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1169174480; called by muse, mutect2, varscan2
- SLC35G2 | c.192del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 17/100 reads (17%) | catalogued as rs750825208; called by mutect2, varscan2
- SLC35G2 | c.640G>A p.V214I | Missense Mutation (SNP) | VAF 39/283 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as rs201316315; called by muse, mutect2, varscan2
- SLC38A10 | c.2798G>A p.R933Q | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1288801757; called by muse, mutect2, varscan2
- SLC3A1 | c.1118C>T p.T373M | Missense Mutation (SNP) | VAF 72/407 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs748102054; called by muse, mutect2, varscan2
- SLC45A4 | c.1327G>A p.A443T (on ENST00000517878 / NM_001286646.2; = p.A392T on NM_001080431.2) | Missense Mutation (SNP) | VAF 64/338 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.068); catalogued as rs1489563197; called by muse, mutect2, varscan2
- SLC46A2 | c.371T>C p.L124P | Missense Mutation (SNP) | VAF 46/251 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763781911; called by muse, mutect2, varscan2
- SLC47A2 | c.1114G>A p.V372M | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs751597777, COSV100328164; called by muse, mutect2
- SLC4A11 | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 127/656 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780171125, CM095208; called by muse, mutect2, varscan2
- SLC4A2 | c.3071G>A p.R1024H | Missense Mutation (SNP) | VAF 20/577 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1177021784, COSV99879603; called by muse, mutect2
- SLC4A3 | c.3108dup p.L1037Afs*35 | Frame Shift Ins (INS) | VAF 60/398 reads (15%) | catalogued as rs757961785; called by mutect2, varscan2
- SLC52A2 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 67/518 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs781916346; called by muse, mutect2, varscan2
- SLC6A1 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 52/306 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs748224785; called by muse, mutect2, varscan2
- SLC7A8 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs540015976, COSV57553238; called by muse, mutect2, varscan2
- SLC9A1 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 69/451 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs138831575; called by muse, mutect2, varscan2
- SLC9A5 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 49/321 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs777947027, COSV55360853; called by muse, mutect2, varscan2
- SLC9A7 | c.1222C>T p.R408* | Nonsense Mutation (SNP) | VAF 38/256 reads (15%) | catalogued as COSV60384826; called by muse, varscan2
- SLCO1B3 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.238); catalogued as rs141602442; called by muse, mutect2, varscan2
- SLCO5A1 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs1444482715, COSV99479876; called by muse, mutect2, varscan2
- SLIT3 | c.4471C>T p.R1491C | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs749166577, COSV100271102; called by muse, mutect2, varscan2
- SLTM | c.1539del p.E514Kfs*8 | Frame Shift Del (DEL) | VAF 18/148 reads (12%) | catalogued as rs1319405514; called by mutect2, varscan2
- SMG6 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 57/360 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as rs762484659; called by muse, mutect2, varscan2
- SMIM13 | c.104del p.L35Yfs*56 | Frame Shift Del (DEL) | VAF 30/175 reads (17%) | catalogued as rs906089964; called by mutect2, pindel, varscan2
- SNIP1 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs760872087; called by muse, mutect2, varscan2
- SNRPB | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs778892584, COSV60015031; called by muse, mutect2, varscan2
- SNU13 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs1000596713; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 24/170 reads (14%) | catalogued as rs768873484; called by mutect2, varscan2
- SNX6 | c.306+1G>A p.X102_splice (on ENST00000652385; = p.X90_splice on NM_152233.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 8/31 reads (26%) | catalogued as rs1330188621; called by muse, mutect2, varscan2
- SOHLH1 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 69/438 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100039992, COSV53681013; called by muse, mutect2, varscan2
- SORL1 | c.2608G>A p.V870I | Missense Mutation (SNP) | VAF 42/256 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs150245521, COSV52763487; called by muse, mutect2, varscan2
- SORL1 | c.5186G>A p.R1729H | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs534646732, COSV52751649; called by muse, mutect2, varscan2
- SPDL1 | c.1222C>T p.R408* | Nonsense Mutation (SNP) | VAF 11/83 reads (13%) | catalogued as rs749690829, COSV99517352; called by muse, mutect2, varscan2
- SPECC1L | c.2773C>T p.R925W | Missense Mutation (SNP) | VAF 65/449 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs199614545; called by muse, mutect2, varscan2
- SPTB | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 87/513 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764534275, COSV67632731; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTBN1 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1367431475; called by muse, mutect2, varscan2
- SPTBN4 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 33/251 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as rs375585194, COSV58957126; called by muse, mutect2, varscan2
- SPTBN5 | c.7636G>A p.D2546N | Missense Mutation (SNP) | VAF 65/388 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as rs537948359, COSV58016529; called by muse, mutect2, varscan2
- SPTY2D1 | c.2027G>A p.R676H | Missense Mutation (SNP) | VAF 44/268 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs755138835, COSV60474639; called by muse, mutect2, varscan2
- SQLE | c.254del p.P85Lfs*25 | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | catalogued as rs760774524; called by mutect2, pindel
- SRCAP | c.7141C>T p.R2381C | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs1430925699, COSV52671221; called by muse, mutect2, varscan2
- SRCAP | c.8302C>T p.R2768W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1220287151; called by muse, varscan2
- STK11IP | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 64/419 reads (15%) | catalogued as rs777047546; called by muse, mutect2, varscan2
- STK11IP | c.945+1G>A p.X315_splice | Splice Site (SNP) | VAF 91/530 reads (17%) | catalogued as rs777066069, COSV55253616; called by muse, mutect2, varscan2
- STKLD1 | c.1429G>A p.V477I | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs782692340; called by muse, mutect2, varscan2
- STRN4 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.206); catalogued as rs373884790; called by muse, mutect2, varscan2
- STXBP5L | c.2732C>T p.P911L | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.348); catalogued as rs910903172; called by muse, mutect2
- SV2B | c.660del p.F220Lfs*25 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | catalogued as rs1210452364; called by mutect2, pindel, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/107 reads (13%) | catalogued as rs770033147; called by mutect2, pindel, varscan2
- SYNE2 | c.10927C>T p.R3643* | Nonsense Mutation (SNP) | VAF 59/328 reads (18%) | catalogued as rs367711497; called by muse, mutect2, varscan2
- SYNPO | c.2066C>A p.A689E (on ENST00000394243 / NM_001166208.2; = p.A445E on NM_007286.6) | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV100302451; called by muse, mutect2, varscan2
- SZT2 | c.9380G>A p.R3127Q (on ENST00000634258 / NM_001365999.1; = p.R3070Q on NM_015284.4) | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV65095598; called by muse, mutect2, varscan2
- TAAR6 | c.116T>C p.F39S | Missense Mutation (SNP) | VAF 59/349 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV51584802; called by muse, mutect2, varscan2
- TAF1 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 45/266 reads (17%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); catalogued as rs1013200589; called by muse, mutect2, varscan2
- TAF1 | c.2930G>A p.R977H (on ENST00000373790 / NM_138923.4; = p.R998H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773557452, COSV52116921; called by muse, mutect2, varscan2
- TAPT1 | c.1613C>T p.T538M | Missense Mutation (SNP) | VAF 53/294 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.151); catalogued as rs374613998; called by muse, mutect2, varscan2
- TAS1R2 | c.2371G>A p.V791M | Missense Mutation (SNP) | VAF 166/943 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as rs773974393, COSV64747823; called by mutect2, varscan2
- TBC1D2 | c.1690G>A p.G564S | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs978281123, COSV100580193; called by muse, mutect2, varscan2
- TBC1D22B | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 42/296 reads (14%) | catalogued as rs758321916; called by muse, mutect2, varscan2
- TBC1D8 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1215707930, COSV100964592; called by muse, mutect2, varscan2
- TBC1D9B | c.2690C>T p.S897L | Missense Mutation (SNP) | VAF 56/245 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs775020533; called by muse, mutect2, varscan2
- TBC1D9B | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 34/329 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs574734327; called by muse, mutect2, varscan2
- TCEAL4 | c.118T>C p.W40R | Missense Mutation (SNP) | VAF 13/248 reads (5%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.045); catalogued as rs1367125740; called by muse, mutect2
- TCF7L2 | c.1105G>A p.V369I (on ENST00000355995 / NM_001367943.1; = p.V346I on NM_030756.5) | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.528); catalogued as COSV53342492; called by muse, mutect2, varscan2
- TEK | c.2426del p.N809Tfs*21 | Frame Shift Del (DEL) | VAF 73/414 reads (18%) | catalogued as COSV66231046; called by mutect2, pindel, varscan2
- TEKT2 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 98/514 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs761848844; called by muse, mutect2, varscan2
- TENM1 | c.7779del p.R2594Gfs*15 | Frame Shift Del (DEL) | VAF 18/162 reads (11%) | catalogued as COSV64442554; called by mutect2, pindel, varscan2
- TENM3 | c.4729G>A p.V1577M | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV69305247; called by muse, mutect2, varscan2
- TENM3 | c.6521G>A p.R2174H | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs751169755, COSV69300050; called by muse, mutect2, varscan2
- TERB1 | c.1108del p.I370Lfs*7 | Frame Shift Del (DEL) | VAF 36/138 reads (26%) | catalogued as rs1391764297; called by mutect2, varscan2
- TGM1 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 88/510 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs369636498; called by muse, mutect2, varscan2
- THBS3 | c.2745del p.R916Vfs*12 | Frame Shift Del (DEL) | VAF 51/347 reads (15%) | catalogued as rs1355720789; called by mutect2, pindel, varscan2
- TIAM2 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 78/423 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as rs1391918156, COSV59700391; called by muse, mutect2, varscan2
- TICAM1 | c.1783A>G p.M595V | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs561021962; called by muse, mutect2, varscan2
- TIE1 | c.743del p.P248Lfs*117 | Frame Shift Del (DEL) | VAF 43/336 reads (13%) | catalogued as rs1417872933, COSV100992023; called by mutect2, pindel, varscan2
- TIMM10 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 55/279 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs751623583; called by muse, mutect2, varscan2
- TLE4 | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.193); catalogued as rs761883732, COSV54629888, COSV54635624; called by muse, mutect2, varscan2
- TLR2 | c.2243G>A p.R748H | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs370330063; called by muse, mutect2, varscan2
- TLR5 | c.11A>G p.H4R | Missense Mutation (SNP) | VAF 53/694 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1210935912, COSV60560750; called by muse, mutect2
- TMBIM1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762435410, COSV99297838; called by muse, mutect2, varscan2
- TMEM150A | c.295G>A p.G99R (on ENST00000334462 / NM_001031738.3; = p.G46R on NM_153342.3) | Missense Mutation (SNP) | VAF 45/240 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1387988974, COSV57817395; called by muse, mutect2, varscan2
- TMEM198 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs568013301, COSV54721763, COSV99524150; called by muse, mutect2, varscan2
- TMEM88B | c.449dup p.R152Afs*? | Frame Shift Ins (INS) | VAF 16/97 reads (16%) | catalogued as rs1171805582; called by mutect2, pindel, varscan2
- TMEM94 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 61/354 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs138050254; called by muse, mutect2, varscan2
- TMIE | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 134/676 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746409545, COSV58405810; called by muse, mutect2, varscan2
- TMPRSS5 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs372456255; called by muse, mutect2, varscan2
- TMTC2 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs777630655; called by muse, mutect2, varscan2
1,157 further variants in this file (517 protein-altering or splice-affecting, 413 silent, 227 other) are not listed here.
